Somatic mutation profile of tumor specimen TCGA-EM-A3FQ-06A (aliquot TCGA-EM-A3FQ-06A-11D-A21A-08) from TCGA case TCGA-EM-A3FQ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 19.6 years (7,176 days).
Specimen TCGA-EM-A3FQ-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0bb2152-d9d5-4af2-a0b7-0d0e35ddaec1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3FQ-10A (Blood Derived Normal), aliquot TCGA-EM-A3FQ-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dde7a45b-9e3a-4582-b463-04cae3c9bac0

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL27A1 | c.1409A>C p.K470T | Missense Mutation (SNP) | VAF 119/295 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV61928160; called by muse, mutect2, varscan2
- DZIP3 | c.2497C>A p.Q833K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.501); catalogued as COSV64312735, COSV64313420; called by muse, mutect2, varscan2
- PCDH11X | c.2473G>A p.V825I | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs377250651, COSV53454579; called by muse, mutect2, varscan2
- PPP2R3B | c.296G>A p.G99D | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.133); catalogued as COSV66813791; called by muse, mutect2
- SLC7A6 | c.478G>C p.D160H | Missense Mutation (SNP) | VAF 8/242 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV54719739; called by muse, mutect2
- WDFY2 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV53290996; called by muse, mutect2, varscan2
- TMEM132B | c.2637G>A p.P879= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as rs191297957; called by muse, mutect2, varscan2
- ZNF835 | c.447G>A p.Q149= | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as COSV73379554; called by muse, mutect2
